Surgical pathology report (de-identified scan), TCGA case TCGA-NK-A7XE, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - Rush University, specimen TCGA-NK-A7XE-01A (Primary Tumor).

[page 1 of 4]
SPECIMEN DATE:
SUBMITTING MD:

ICD O-3
Carcinoma, squamous cell NOS
807013
Site Lung, upper lobe
C34.1
JW 10/4/13

Final

Clinical Data Repository* This report may not match the original report
format

REPORT DATE:

FINAL DIAGNOSIS

a. (Bronchus, left tracheal bronchial angle, frozen): one benign lymph node

b. (pulmonary ligament, inferior): 3 benign lymph nodes

c. (lung, left, resection): Invasive squamous cell carcinoma, grade 2, measuring 12 cm with extension into perihilar mediastinal fibroadipose tissue. Lymphatic permeation by tumor cells present. Intra and perineural invasion by tumor cells also present. 3/8 perihilar lymph nodes show metastatic tumor. Margins of resection free of tumor, including; bronchial, vascular and soft tissue. Stage T4N2PL3.

d. (Lymph nodes; level 7, subcarinal): 3/14 lymph nodes with metastatic squamous cell carcinoma with extracapsular extension

e. (Lymph nodes; level 9): 3 lymph nodes negative for metastatic tumor

Attending Pathologist:

* Electronically signed Pathology

Resident:

INTRAOPERATIVE CONSULTATION

A.FROZEN:LEFT TRACHEAL BRONCHIAL ANGLE: Lymph node. No carcinoma seen.

(A91,

Smear).

Intraoperative consultation pathologist.

C. LEFT LUNG, FROZEN ON BRONCHIAL MARGIN: Squamous cell carcinoma. Bronchial margin free of tumor. (C91)

[page 2 of 4]
Intraoperative consultation pathologist
Intraoperative consultation resident

NOTE

Lung Cancer Summary

Specimen type: Lung resection

Procedure: Left lung resection, pneumonectomy

Specimen integrity: intact

Tumor location: Left upper lobe

Tumor focality: unifocal

Tumor size: 12 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Grade 2

Treatment effect: Not applicable

Status of margins:

Bronchial: Negative

Vascular: Negative

Parenchymal: Negative

Pleural: Negative

Visceral/Parietal pleural invasion: Mediastinal pleura involved

Lymphatic vascular invasion: present

Lymph node status: positive (level 7, and peri-hilar)

Extension into other structures: present into perihilar mediastinal
fibroadipose tissue

Non-neoplastic pathology: N/A

TMN stage:

T4 N2PL3

[page 3 of 4]
GROSS DESCRIPTION

A. The specimen is labeled left tracheal bronchial angle. Received fresh for frozen section is a 0.9 x 0.3 x 0.2 cm irregular fragment of red-tan tissue containing possible pink-tan lymphoid tissue. The specimen is entirely submitted for frozen section with the remnant placed in cassette A1. Touch prep and smear are prepared.

B. The specimen is labeled inferior pulmonary ligament. Received in formalin is a 1.1 x 0.6 x 0.5 cm irregular fragment of soft red-tan tissue. The specimen is trisected and entirely submitted in cassette B1.

D. The specimen is labeled level VII subcarinal node. Received in formalin is a 2.5 x 1.3 x 1.0 cm lymph node and a separate 3.4 x 2.0 x 0.6 cm aggregate of multiple roughened red-tan fibroadipose tissue fragments containing possible lymphoid tissue. Sectioning through the lymph node shows a solid pale tan cut surface. Sections are submitted as follows: D1-3 - lymph node trisected, D4 and D5 - remaining fragments containing possible lymphoid tissue.

C. The specimen is labeled "left lung frozen on bronchial" is a 487 g left pneumonectomy with anthracotic pleural surface measures 26.1 x 15.5 x 7.5 cm. Both lobes were identified. Inked at the site of frozen section and it has a staple line at the vascular margin.

The specimen was serially sectioned to reveal an indistinct gray tan mass measuring 12.0 x 7.5 x 6.5 cm located in the upper lobe. The mass is obstructing the main bronchus and is 1 cm away from the bronchial margin. The mass is abutting pleural surface. Recovered total of 7 lymph nodes ranging in size from 0.5 x 0.5 x 0.2 cm to 1.9 x 1.0 x 1.0 cm. Rest of lung tissue is spongy frothy dark red.

Sections are submitted as follow:

- C1-2 vascular margin
- C3 mass with a vasculature
- C 4-5 mass with bronchus
- C 6 representative section from the mass
- C 7-8 LYMPH nodes
- C9 bronchial lymph node bisected
- C 10-11 unremarkable lung

E. The specimen is labeled level IX node. Received in formalin is a 3.5 x 2.5 x 1.0 cm aggregate of multiple red-tan fibroadipose tissue fragments containing 2 possible lymph nodes (1.3 and 2.3 cm in greatest dimension). The specimen is entirely submitted as follows: E1 - largest lymph node, bisected, E2 - one lymph node, bisected, E3 and E4 - remaining fibroadipose tissue

[page 4 of 4]
fragments.

SPECIMEN(S) RECEIVED

A: FROZEN:LEFT TRACHEAL BRONCHIAL ANGLE

B: INFERIOR PULMONARY LIGAMENT

C: LEFT LUNG, FROZEN ON BRONCHIAL MARGIN

D: LEVEL 7 SUBCARINAL NODE

E: LEVEL 9 NODE

* The above listed tests (if any) were developed and the performance characteristics determined by _____ These tests have not been cleared or approved for commercial use by the U.S. Food and Drug Administration. The FDA has determined that FDA review is not required for such in-house assays. (21 CFR 809.30(e))

OPERATIVE INFORMATION

DIAGNOSIS: LUNG CA; PROCEDURE: DISSECTION MEDIASTINAL LYMPH NODE, THORACOTOMY
PNEUMONECTOMY

INTRADEPARTMENT CONSULTATION PATHOLOGIST: QA COMMITTEE

ICD-9(s): 162.3

CPT(s): A; 88305, 88331, 88333, 88334

B; 88304

C; 88309, 88331

D; 88307

E; 88307

The attending pathologist was physically present when this specimen was diagnosed, and actively participated in all key decisions.

Diagnostic Discrepancy		

hw 9/26/13
prostate
9/26/2013

Source: NCI Genomic Data Commons file 29694fa7-def4-4ead-9073-a9fccca67b01 (TCGA-NK-A7XE.72D0E0B9-F05B-458F-9036-91A8DE553E8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).